Somatic mutation profile of tumor specimen TARGET-15-SJMPAL012422-09A.2 (aliquot TARGET-15-SJMPAL012422-09A.2-01D) from TARGET case TARGET-15-SJMPAL012422, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,552 days).
Specimen TARGET-15-SJMPAL012422-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eede0913-6a28-4286-b30f-3dcdd9840acd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL012422-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL012422-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/506b25b7-6ad3-4360-bf9e-1ece8b1dbe67

The open-access MAF lists 17 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, RNA 1, Frame Shift Ins 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMPD3 | c.374A>G p.Y125C (on ENST00000396553 / NM_001025389.2; = p.Y134C on NM_000480.3) | Missense Mutation (SNP) | VAF 74/151 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.195); catalogued as rs781521325; called by muse, mutect2, varscan2
- RPS6KA6 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT deleterious (0.05); PolyPhen benign (0.18); catalogued as COSV53125495; called by muse, mutect2, varscan2
- ARHGAP42 | c.1129A>G p.T377A | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DIS3L2 | c.820_821insAGGCC p.R274Qfs*66 | Frame Shift Ins (INS) | VAF 55/134 reads (41%) | called by mutect2, pindel, varscan2
- DNAH7 | c.8458G>T p.A2820S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); called by mutect2, varscan2
- HYDIN | c.4490A>T p.D1497V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF4B | c.302C>A p.A101E | Missense Mutation (SNP) | VAF 89/225 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- NAP1L3 | c.932T>C p.I311T | Missense Mutation (SNP) | VAF 61/63 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- NCAPH2 | c.1116C>A p.D372E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.019); called by muse, mutect2
- POLR2E | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- CTBP1 | c.360G>T p.V120= | Silent (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2
- FNDC7 | c.1332C>A p.G444= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- FREM1 | c.2937G>A p.L979= | Silent (SNP) | VAF 24/34 reads (71%) | called by muse, mutect2, varscan2
- TTC6 | c.966T>C p.A322= (on ENST00000267368; = p.A1688= on NM_001310135.3) | Silent (SNP) | VAF 37/73 reads (51%) | called by muse, mutect2, varscan2
- CD3D | c.*28G>A | 3'UTR (SNP) | VAF 67/134 reads (50%) | called by muse, mutect2, varscan2
- IRF3 | c.165+228G>A | Intron (SNP) | VAF 54/107 reads (50%) | catalogued as rs763860251; called by muse, mutect2, varscan2
- SMPD4BP | n.2562_2563del | RNA (DEL) | VAF 34/68 reads (50%) | called by mutect2, pindel*
